FM case AD1515 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/fcd9637f-00f2-49e9-bb87-94e556d5d7eb

Male, 53.4 years: Glioblastoma (ICD-O-3 9440/3) of the nervous system. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Tumor.
